Somatic mutation profile of tumor specimen TCGA-BP-5184-01A (aliquot TCGA-BP-5184-01A-01D-1429-08) from TCGA case TCGA-BP-5184, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.1 years (19,746 days).
Specimen TCGA-BP-5184-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d729c317-fef8-4ffa-8e93-4d61fb1395b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5184-11A (Solid Tissue Normal), aliquot TCGA-BP-5184-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab3e55ad-821b-4851-8c35-bec9da86f735

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 17, Silent 10, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.974A>G p.E325G | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV55960744; called by muse, mutect2, varscan2
- ALPK2 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV64496060; called by muse, mutect2, varscan2
- AP001781.2 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52790431; called by muse, mutect2, varscan2
- CSPP1 | c.807A>T p.Q269H (on ENST00000676605; = p.Q228H on NM_024790.6) | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV51590950; called by muse, mutect2, varscan2
- GRIA4 | c.2387G>A p.G796E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV56914693; called by muse, mutect2, varscan2
- HBB | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58942981; called by muse, mutect2, varscan2
- KCNN4 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775470701, COSV53456821; called by muse, mutect2, varscan2
- MARCHF10 | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs760323928, COSV60889954; called by muse, mutect2
- NCAPD3 | c.1838G>A p.C613Y | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs757129034, COSV73258579; called by muse, mutect2, varscan2
- PCF11 | c.1784A>G p.K595R | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.874); catalogued as COSV53536648; called by muse, mutect2, varscan2
- PMVK | c.98T>A p.L33H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63786111; called by muse, mutect2, varscan2
- PRKD1 | c.2356G>T p.D786Y | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59581969; called by muse, mutect2, varscan2
- SRC | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV62441622; called by muse, mutect2
- THAP9 | c.2592T>A p.D864E | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56357430; called by muse, mutect2, varscan2
- UNC93A | c.1090T>C p.W364R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746982648, COSV57810452; called by muse, mutect2, varscan2
- UTRN | c.8666T>A p.I2889N | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV62312071; called by muse, mutect2, varscan2
- ZNF592 | c.425G>T p.S142I | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55438985; called by muse, mutect2, varscan2
- CHRNA1 | c.984_986del p.F329del (on ENST00000261007 / NM_001039523.3; = p.F304del on NM_000079.4) | In Frame Del (DEL) | VAF 30/132 reads (23%) | called by mutect2, pindel, varscan2
- OLFM2 | c.275_276dup p.V93Mfs*31 | Frame Shift Ins (INS) | VAF 17/104 reads (16%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3480del p.G1161Afs*57 (on ENST00000296302 / NM_001366071.2; = p.G1136Afs*57 on NM_018313.5) | Frame Shift Del (DEL) | VAF 39/147 reads (27%) | called by mutect2, pindel, varscan2
- VHL | c.430_433del p.G144Sfs*14 | Frame Shift Del (DEL) | VAF 64/235 reads (27%) | called by mutect2, pindel, varscan2
- CACHD1 | c.1521T>C p.T507= | Silent (SNP) | VAF 45/220 reads (20%) | catalogued as COSV51556595, COSV51558763; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1731C>T p.T577= (on ENST00000357886 / NM_001365728.1; = p.T563= on NM_016082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV55786615, COSV55786984; called by muse, mutect2, varscan2
- ELOVL1 | c.684G>A p.Q228= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV60522596, COSV60522814; called by muse, mutect2, varscan2
- FGF13 | c.702C>T p.N234= | Silent (SNP) | VAF 84/160 reads (53%) | catalogued as rs371293414, COSV59545317; called by muse, mutect2, varscan2
- HERC5 | c.2691C>T p.I897= | Silent (SNP) | VAF 16/193 reads (8%) | catalogued as COSV52043698; called by muse, mutect2
- NRG2 | c.1431C>T p.N477= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as rs761477100, COSV56832728; called by muse, mutect2, varscan2
- TRPV4 | c.1902C>T p.S634= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as rs576390203, COSV55682787; called by muse, varscan2
- TSNARE1 | c.852C>T p.S284= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100210896, COSV56181909; called by muse, mutect2, varscan2
- VPS51 | c.963C>A p.A321= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV54209047; called by muse, mutect2, varscan2
- ZC3H13 | c.702T>C p.D234= | Silent (SNP) | VAF 22/269 reads (8%) | catalogued as rs374265880; called by muse, mutect2
